Somatic mutation profile of tumor specimen TCGA-22-0940-01A (aliquot TCGA-22-0940-01A-01D-1521-08) from TCGA case TCGA-22-0940, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.9 years (26,272 days).
Specimen TCGA-22-0940-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0954b2e-bd5a-4eb7-8604-8742ccb59a9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-0940-11A (Solid Tissue Normal), aliquot TCGA-22-0940-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c08ad8f8-6ae3-4fa9-a9c1-2714d5ba3fdf

The open-access MAF lists 224 somatic variants for this specimen: 173 protein-altering or splice-affecting, 45 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 45, Frame Shift Del 9, Nonsense Mutation 8, Splice Site 4, Intron 3, Frame Shift Ins 2, RNA 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 22/49 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4055T>C p.L1352P (on ENST00000303395 / NM_001202435.3; = p.L1341P on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794726821, CM1511244, COSV100320487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3461G>T p.R1154L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99067430, COSV99285825; called by muse, mutect2, varscan2
- ABCB5 | c.693G>T p.L231F | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.139); catalogued as COSV99328416; called by muse, mutect2, varscan2
- ABCC11 | c.3499G>C p.G1167R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as COSV100750769; called by muse, mutect2, varscan2
- ACO1 | c.2121C>A p.N707K | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100008139; called by muse, mutect2
- ACOX1 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV99503595; called by muse, mutect2, varscan2
- ACSS3 | c.1721C>G p.S574* | Nonsense Mutation (SNP) | VAF 48/287 reads (17%) | catalogued as COSV99698855; called by muse, mutect2, varscan2
- ACTR5 | c.1795G>A p.G599S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99710039; called by muse, mutect2, varscan2
- ADAMTS16 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 54/161 reads (34%) | catalogued as COSV56996280, COSV57006645; called by muse, mutect2, varscan2
- ADAMTS19 | c.1328G>T p.R443M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV50735197, COSV99178846; called by muse, mutect2, varscan2
- ADAMTS20 | c.4252G>A p.D1418N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.16); catalogued as COSV101166264, COSV67127896; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4867G>A p.D1623N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs750437275, COSV99718908; called by muse, mutect2, varscan2
- ADD1 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs768137427, COSV53270893; called by muse, mutect2, varscan2
- AGAP4 | c.1987G>C p.V663L | Missense Mutation (SNP) | VAF 26/277 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as rs782270678, COSV101432663; called by muse, mutect2
- ALOX15 | c.1070T>C p.L357P | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99541422; called by muse, mutect2, varscan2
- AMBN | c.1085C>A p.P362H | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100534356; called by muse, mutect2, varscan2
- ANK2 | c.8398G>A p.D2800N | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.361); catalogued as COSV100001729; called by muse, mutect2, varscan2
- ANKRD30A | c.452T>C p.I151T (on ENST00000611781; = p.I95T on NM_052997.2) | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100653568, COSV64617938; called by muse, mutect2, varscan2
- APBB1 | c.1208A>T p.Y403F | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100194042; called by muse, mutect2, varscan2
- ARHGAP30 | c.1412G>C p.G471A | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV100920276; called by muse, mutect2, varscan2
- ARL6IP6 | c.583T>C p.F195L | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as COSV100424012; called by muse, mutect2, varscan2
- ASIC5 | c.1505T>A p.I502K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV101611138; called by muse, mutect2
- ATP7B | c.3565T>A p.C1189S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99666456; called by muse, varscan2
- BMPER | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99779635; called by muse, mutect2, varscan2
- C9orf153 | c.79T>A p.Y27N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100188656; called by muse, mutect2
- CADPS | c.3693C>G p.D1231E | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.944); catalogued as COSV99338388; called by muse, mutect2
- CAV1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV61953769; called by muse, mutect2, varscan2
- CDC20B | c.1410T>A p.D470E | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV99696921; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs752398646; called by mutect2, pindel, varscan2
- CDH6 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99419244; called by muse, mutect2, varscan2
- CENPE | c.3340G>C p.E1114Q | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV99477981; called by muse, mutect2, varscan2
- CFTR | c.2816A>T p.H939L | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as CM962472, CX993898, COSV99136293; called by muse, mutect2, varscan2
- CHRM2 | c.319A>C p.S107R | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100281317; called by muse, mutect2, varscan2
- CHURC1 | c.256+1G>A p.X86_splice | Splice Site (SNP) | VAF 21/98 reads (21%) | catalogued as rs779160320, COSV100767452; called by muse, mutect2, varscan2
- CLCA1 | c.1873A>T p.S625C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs557341333, COSV99322370; called by muse, mutect2, varscan2
- CLEC4F | c.727G>C p.A243P | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV99713744; called by muse, mutect2, varscan2
- CLRN2 | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.994); catalogued as COSV101566458; called by muse, mutect2, varscan2
- CLVS1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 18/117 reads (15%) | catalogued as rs756911932, COSV100370014; called by muse, mutect2, varscan2
- CNOT1 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as COSV100409320; called by muse, mutect2, varscan2
- COL22A1 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100278564; called by muse, mutect2, varscan2
- CORIN | c.2767G>T p.D923Y | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV99903656; called by muse, mutect2, varscan2
- CORIN | c.1217A>G p.K406R | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99903658; called by muse, mutect2, varscan2
- CRB1 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV100957886; called by muse, mutect2, varscan2
- CSMD1 | c.2317C>A p.P773T (on ENST00000520002; = p.P772T on NM_033225.6) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100148096; called by muse, varscan2
- DACH2 | c.1222C>A p.H408N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV100913247; called by muse, mutect2, varscan2
- DCAF4L1 | c.1121del p.G374Afs*120 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | catalogued as COSV100296104; called by mutect2, pindel, varscan2
- DDX3X | c.1805G>A p.R602Q (on ENST00000399959; = p.R603Q on NM_001356.5) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101302338; called by muse, mutect2, varscan2
- DIRAS2 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV101005860; called by muse, mutect2, varscan2
- DLG1 | c.1943A>T p.E648V | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100015373; called by muse, mutect2
- DMP1 | c.496A>G p.R166G | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99218736; called by muse, mutect2, varscan2
- DMXL2 | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99196381; called by muse, mutect2, varscan2
- DNAAF4 | c.385G>C p.A129P | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs750814401, COSV100336736; called by muse, mutect2, varscan2
- DNAH10 | c.5293G>A p.E1765K (on ENST00000409039; = p.E1704K on NM_207437.3) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs762344435, COSV101292272; called by muse, mutect2, varscan2
- DPEP3 | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.706); catalogued as COSV99262714; called by muse, mutect2
- DPYSL5 | c.394G>T p.V132L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs139539355, COSV56509634; called by muse, mutect2, varscan2
- DSTYK | c.2144G>C p.G715A | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100904572; called by muse, mutect2
- ENPP3 | c.1483A>T p.I495F | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV100717311; called by muse, mutect2, varscan2
- EPB41L3 | c.519dup p.Q174Tfs*12 | Frame Shift Ins (INS) | VAF 30/134 reads (22%) | catalogued as rs1474424767; called by mutect2, varscan2
- ERCC6L2 | c.2087A>G p.K696R | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1300174166, COSV99998624; called by muse, mutect2, varscan2
- EXOC7 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1046001893; called by muse, mutect2
- FBLN7 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV100485556; called by muse, mutect2, varscan2
- FGA | c.1002G>A p.W334* | Nonsense Mutation (SNP) | VAF 48/304 reads (16%) | catalogued as CM001690, COSV100120387; called by muse, mutect2, varscan2
- GARNL3 | c.220-1G>A p.X74_splice | Splice Site (SNP) | VAF 29/132 reads (22%) | catalogued as COSV59223405; called by muse, mutect2, varscan2
- GCNT4 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV100466488; called by muse, mutect2, varscan2
- GPAA1 | c.1544T>C p.L515P | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554764276, COSV100731143; called by muse, mutect2, varscan2
- GRXCR1 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV67674524; called by muse, mutect2, varscan2
- HACE1 | c.1247A>G p.Y416C | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99493686; called by muse, mutect2, varscan2
- HASPIN | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 27/127 reads (21%) | catalogued as COSV53994350, COSV99560971; called by muse, mutect2, varscan2
- HEPACAM2 | c.890C>T p.P297L (on ENST00000394468 / NM_001039372.4; = p.P285L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100506569; called by muse, mutect2, varscan2
- HHLA2 | c.915G>C p.M305I | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100755348, COSV100755394; called by muse, mutect2
- ILF3 | c.2464G>A p.G822S | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as rs137952515; called by muse, mutect2, varscan2
- JAM3 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.58); catalogued as COSV100138184; called by muse, mutect2, varscan2
- KCNA5 | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99363909; called by muse, mutect2, varscan2
- KIN | c.528A>T p.Q176H | Missense Mutation (SNP) | VAF 65/436 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV101092574; called by muse, mutect2, varscan2
- KIR2DL1 | c.371-1G>T p.X124_splice | Splice Site (SNP) | VAF 129/544 reads (24%) | catalogued as COSV52407583; called by muse, mutect2
- KRBA1 | c.1015C>G p.Q339E | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV99752708; called by muse, mutect2
- KRT13 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 69/339 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.241); catalogued as COSV99877369; called by muse, mutect2, varscan2
- KRT74 | c.1178G>C p.G393A | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977533; called by muse, mutect2, varscan2
- LARP7 | c.833A>G p.K278R | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.997); catalogued as COSV100135153; called by muse, mutect2, varscan2
- LCN2 | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs749080993, COSV52981780, COSV99478201; called by muse, mutect2, varscan2
- LMOD2 | c.37T>C p.Y13H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101505448; called by muse, mutect2, varscan2
- LPL | c.1242C>A p.Y414* | Nonsense Mutation (SNP) | VAF 21/146 reads (14%) | catalogued as COSV100255602; called by muse, mutect2, varscan2
- LRP1B | c.11132-2A>T p.X3711_splice | Splice Site (SNP) | VAF 16/101 reads (16%) | catalogued as COSV101257251; called by muse, mutect2, varscan2
- LYZ | c.47T>A p.V16D | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV99720125; called by muse, mutect2, varscan2
- MAGEB6 | c.923G>A p.W308* | Nonsense Mutation (SNP) | VAF 88/226 reads (39%) | catalogued as COSV100983746; called by muse, mutect2, varscan2
- MAGEC1 | c.2017C>A p.Q673K | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV99035707, COSV99595741; called by muse, mutect2, varscan2
- MAGEC1 | c.2404C>A p.P802T | Missense Mutation (SNP) | VAF 98/288 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as COSV53572788, COSV99595743; called by muse, mutect2, varscan2
- MAGEL2 | c.3077C>G p.A1026G | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as COSV100045952; called by muse, mutect2, varscan2
- MTERF3 | c.521A>T p.E174V | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV99749777; called by muse, mutect2, varscan2
- MYH1 | c.3863C>T p.S1288L | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99875976; called by muse, mutect2, varscan2
- NAV3 | c.899A>C p.Q300P | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99891154; called by muse, mutect2, varscan2
- NRG4 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.804); catalogued as COSV101204859; called by muse, mutect2, varscan2
- NRK | c.1512G>C p.Q504H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99687846; called by muse, mutect2, varscan2
- OR14K1 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 146/339 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99315209; called by muse, mutect2, varscan2
- OR2G6 | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as COSV100598173, COSV100598367; called by muse, mutect2, varscan2
- OR2K2 | c.314C>A p.A105D (on ENST00000374428; = p.A76D on NM_205859.2) | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV100235307; called by muse, mutect2, varscan2
- OR5R1 | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs201450981, COSV100393447, COSV56572037; called by muse, mutect2, varscan2
- OR6C1 | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV101110513; called by muse, mutect2, varscan2
- OTOL1 | c.1175A>T p.Y392F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.445); catalogued as COSV100020003; called by muse, mutect2, varscan2
- PCDH15 | c.2673T>A p.S891R | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV100221291; called by muse, mutect2, varscan2
- PCDHA13 | c.1554C>A p.Y518* | Nonsense Mutation (SNP) | VAF 31/168 reads (18%) | catalogued as COSV56528392, COSV99166429; called by muse, mutect2, varscan2
- PCDHGA7 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54015999, COSV99538597; called by muse, mutect2
- PDE11A | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV100628862; called by muse, mutect2, varscan2
- PDK4 | c.329A>T p.Q110L | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99138828; called by muse, mutect2, varscan2
- PLCL1 | c.2756C>A p.P919Q | Missense Mutation (SNP) | VAF 46/916 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as COSV101406972; called by muse, mutect2
- PLXNB2 | c.4057C>G p.L1353V | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834062; called by muse, varscan2
- POTEE | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV100387964, COSV100388294; called by muse, mutect2
- PPFIA2 | c.2744C>A p.A915E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1294674117, COSV100333478, COSV61041031; called by muse, mutect2, varscan2
- PXDN | c.2119G>T p.D707Y | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53235439, COSV99413551; called by muse, mutect2, varscan2
- PYGL | c.1544A>G p.D515G | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99368654; called by muse, mutect2, varscan2
- RELN | c.3257T>C p.V1086A | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV100633774, COSV59004057; called by muse, mutect2, varscan2
- RFX6 | c.1486C>A p.L496M | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100263747, COSV60583497; called by muse, mutect2, varscan2
- RIMS1 | c.177G>T p.R59S | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV53448727; called by muse, mutect2, varscan2
- RIPK4 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100204960; called by muse, mutect2, varscan2
- SCN11A | c.2513G>T p.R838L | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs149681198, COSV100181606; called by muse, mutect2, varscan2
- SDC2 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100143446; called by muse, mutect2, varscan2
- SEC23A | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs541602739, COSV100305483; called by muse, mutect2, varscan2
- SEMA5A | c.2493G>T p.Q831H | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101228290; called by muse, mutect2, varscan2
- SEMA6D | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374815414, COSV100316985; called by muse, mutect2, varscan2
- SGK2 | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs763850331, COSV100414595, COSV100414657; called by muse, mutect2, varscan2
- SI | c.2879G>T p.C960F | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100015605; called by muse, mutect2, varscan2
- SIDT2 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV99637703; called by muse, mutect2, varscan2
- SLC12A1 | c.536G>T p.W179L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100372370; called by muse, mutect2, varscan2
- SLC12A5 | c.2637G>A p.M879I (on ENST00000454036 / NM_001134771.2; = p.M856I on NM_020708.5) | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99716074; called by muse, mutect2, varscan2
- SLC18A2 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as rs1363906830, COSV100041676; called by muse, mutect2
- SLC24A5 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99981675; called by muse, mutect2, varscan2
- SLC45A2 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV56872959; called by muse, mutect2, varscan2
- SLITRK5 | c.371C>A p.A124D | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100280769; called by muse, mutect2, varscan2
- SMARCAD1 | c.2576T>C p.L859S | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100758932; called by muse, mutect2, varscan2
- SOS1 | c.3964G>A p.D1322N | Missense Mutation (SNP) | VAF 51/323 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.355); catalogued as rs1167931335, COSV101216946; called by muse, mutect2, varscan2
- SPTAN1 | c.6691G>T p.G2231W | Missense Mutation (SNP) | VAF 229/917 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100823583; called by muse, mutect2, varscan2
- SRRM4 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.445); catalogued as rs559217766, COSV57412500; called by muse, mutect2, varscan2
- STX16 | c.437G>A p.R146Q (on ENST00000371141 / NM_001001433.3; = p.R125Q on NM_003763.6) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs761484020, COSV100397422; called by muse, mutect2
- TARBP1 | c.2794G>T p.A932S | Missense Mutation (SNP) | VAF 117/266 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.412); catalogued as COSV99241645; called by muse, mutect2, varscan2
- TECPR2 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100849996; called by muse, mutect2, varscan2
- TMEM225 | c.668G>T p.W223L | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100902764, COSV100902811; called by muse, mutect2, varscan2
- TNR | c.1078C>G p.Q360E | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV99689699; called by muse, mutect2, varscan2
- TOX | c.369G>T p.M123I | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100812741; called by muse, mutect2, varscan2
- TP53 | c.818del p.R273Lfs*72 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | catalogued as CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; called by mutect2, pindel, varscan2
- TRIM56 | c.383G>T p.C128F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100047350; called by muse, mutect2, varscan2
- TRIOBP | c.6893A>C p.K2298T (on ENST00000644935 / NM_001039141.3; = p.K585T on NM_007032.5) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100730862; called by muse, mutect2, varscan2
- TTLL9 | c.448C>A p.H150N | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.81); PolyPhen probably damaging (1); catalogued as COSV100206763; called by muse, mutect2
- TUBE1 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV100898283; called by muse, mutect2, varscan2
- TYR | c.466T>A p.Y156N | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV99634231; called by muse, mutect2, varscan2
- UNC13C | c.2420C>A p.A807D | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52848675, COSV99517581; called by muse, mutect2, varscan2
- UNC5D | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV99775339; called by muse, mutect2, varscan2
- UPF1 | c.3257C>T p.P1086L (on ENST00000599848 / NM_001297549.2; = p.P1075L on NM_002911.4) | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs767300705, COSV53200601, COSV99439599; called by muse, mutect2, varscan2
- USP42 | c.3779G>A p.R1260K | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374151941, COSV60361394; called by muse, mutect2, varscan2
- USP43 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV99556694; called by mutect2, varscan2
- VPS13C | c.4694C>T p.S1565F (on ENST00000644861 / NM_020821.3; = p.S1522F on NM_017684.5) | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV99828512; called by muse, mutect2, varscan2
- VWA3B | c.2993T>C p.M998T | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV101346034; called by muse, mutect2, varscan2
- WASHC5 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as rs753133551, COSV100572836; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR17 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99707603; called by muse, mutect2, varscan2
- WDR17 | c.2369T>A p.F790Y | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.977); catalogued as COSV99707606; called by muse, mutect2, varscan2
- WDR36 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV101540803; called by muse, mutect2, varscan2
- WDR72 | c.1555C>G p.P519A | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV100854486; called by muse, mutect2, varscan2
- WNT9A | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as rs964011624, COSV99688243; called by muse, mutect2, varscan2
- YES1 | c.668A>C p.Y223S | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100099581; called by muse, mutect2, varscan2
- ZBTB44 | c.678A>T p.L226F | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV100777279; called by muse, mutect2, varscan2
- ZHX3 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs139157503, CM121424; called by muse, mutect2, varscan2
- ZNF235 | c.2162G>T p.S721I | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99349470; called by muse, mutect2, varscan2
- ZNF257 | c.1310G>A p.G437D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs372577233, COSV71309362; called by muse, mutect2, varscan2
- ZSWIM8 | c.4630C>A p.P1544T (on ENST00000605216 / NM_001242487.2; = p.P1549T on NM_015037.3) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100013999; called by muse, mutect2, varscan2
- CEP164 | c.893del p.G298Afs*31 | Frame Shift Del (DEL) | VAF 46/231 reads (20%) | called by mutect2, pindel, varscan2
- CYTIP | c.988dup p.R330Pfs*40 | Frame Shift Ins (INS) | VAF 17/145 reads (12%) | called by pindel, varscan2
- DSE | c.1271del p.G424Dfs*61 | Frame Shift Del (DEL) | VAF 13/103 reads (13%) | called by mutect2, pindel, varscan2
- FAT3 | c.13082del p.P4361Qfs*8 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- FLII | c.1987del p.Q663Rfs*4 | Frame Shift Del (DEL) | VAF 46/278 reads (17%) | called by mutect2, pindel, varscan2
- KY | c.44_55del p.L15_V18del | In Frame Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- MARK2 | c.1620del p.N541Tfs*75 (on ENST00000402010 / NM_001039469.2; = p.N507Tfs*75 on NM_017490.4) | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, varscan2
- RAD18 | c.1222del p.D408Tfs*40 | Frame Shift Del (DEL) | VAF 17/108 reads (16%) | called by mutect2, pindel, varscan2
- RHEBL1 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADGRF5 | c.2850C>T p.G950= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs369402264, COSV51938125; called by muse, mutect2, varscan2
- ADGRL3 | c.2847G>A p.T949= (on ENST00000506720 / NM_001322402.2; = p.T881= on NM_015236.6) | Silent (SNP) | VAF 71/513 reads (14%) | catalogued as rs750203484, COSV101547134; called by muse, mutect2, varscan2
- ALCAM | c.297T>C p.S99= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as COSV100064815; called by muse, mutect2
- ANK3 | c.3048C>T p.A1016= (on ENST00000280772 / NM_001320874.2; = p.A150= on NM_001149.3) | Silent (SNP) | VAF 23/157 reads (15%) | catalogued as COSV99780064; called by muse, mutect2
- BIRC3 | c.417A>T p.S139= | Silent (SNP) | VAF 77/307 reads (25%) | catalogued as COSV99679901; called by muse, mutect2, varscan2
- BRINP1 | c.501C>A p.L167= | Silent (SNP) | VAF 38/178 reads (21%) | catalogued as COSV99775498; called by muse, mutect2, varscan2
- CD19 | c.1386G>A p.E462= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as CD062127, COSV100218136; called by muse, mutect2, varscan2
- CDHR1 | c.2454C>T p.L818= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as COSV100258890; called by muse, mutect2, varscan2
- CFAP251 | c.1350C>T p.S450= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as COSV99996135; called by muse, mutect2, varscan2
- CLRN2 | c.342C>A p.V114= | Silent (SNP) | VAF 48/194 reads (25%) | catalogued as COSV101566457; called by muse, mutect2, varscan2
- CMYA5 | c.7410G>A p.K2470= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV101484052, COSV101484416; called by muse, mutect2, varscan2
- COL26A1 | c.1270C>T p.L424= (on ENST00000313669 / NM_001278563.3; = p.L422= on NM_133457.4) | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100561771; called by muse, mutect2, varscan2
- CSHL1 | c.654C>T p.G218= (on ENST00000309894 / NM_022581.3; = p.G124= on NM_001318.4) | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as rs200129211; called by muse, mutect2, varscan2
- CSMD3 | c.1056C>T p.T352= | Silent (SNP) | VAF 32/168 reads (19%) | catalogued as COSV99834823; called by muse, mutect2, varscan2
- EZH1 | c.1059C>T p.P353= | Silent (SNP) | VAF 38/215 reads (18%) | catalogued as COSV101331366; called by muse, mutect2, varscan2
- FAM111B | c.1776G>A p.V592= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as rs202177353; called by muse, mutect2, varscan2
- GALNT17 | c.1713G>T p.V571= | Silent (SNP) | VAF 34/196 reads (17%) | catalogued as COSV100353990; called by muse, mutect2, varscan2
- GNPDA1 | c.204C>T p.T68= | Silent (SNP) | VAF 44/284 reads (15%) | catalogued as COSV100257557; called by muse, mutect2, varscan2
- IGKV3D-20 | c.91C>T p.L31= | Silent (SNP) | VAF 35/201 reads (17%) | catalogued as rs749001401; called by muse, mutect2, varscan2
- IGSF9B | c.1434G>A p.L478= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs1266269394, COSV100317673; called by muse, mutect2, varscan2
- ITGB3 | c.1986T>C p.R662= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV101457609; called by muse, mutect2, varscan2
- ITM2A | c.393C>A p.P131= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs764375775, COSV100964458; called by muse, mutect2, varscan2
- KDR | c.1050C>A p.I350= | Silent (SNP) | VAF 35/252 reads (14%) | catalogued as rs762537157, COSV99817768; called by muse, mutect2, varscan2
- MNDA | c.795C>T p.V265= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs756721375, COSV100933341, COSV63741024; called by muse, mutect2, varscan2
- MUC16 | c.40467C>T p.N13489= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs1184375183, COSV101109908, COSV66693138; called by muse, mutect2, varscan2
- NRK | c.3507T>A p.A1169= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV99687853; called by muse, mutect2, varscan2
- OR10Q1 | c.147C>A p.I49= | Silent (SNP) | VAF 21/182 reads (12%) | catalogued as COSV100372284; called by muse, mutect2, varscan2
- OR51Q1 | c.219G>C p.L73= | Silent (SNP) | VAF 44/265 reads (17%) | catalogued as COSV100332939; called by muse, mutect2, varscan2
- OR5F1 | c.648C>A p.S216= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV99558647; called by muse, mutect2
- PNMA8A | c.93A>T p.P31= | Silent (SNP) | VAF 59/159 reads (37%) | catalogued as COSV100562332; called by muse, mutect2, varscan2
- POLE | c.4368A>G p.S1456= | Silent (SNP) | VAF 70/373 reads (19%) | catalogued as COSV100266762; called by muse, mutect2, varscan2
- PSG3 | c.1017T>A p.P339= | Silent (SNP) | VAF 93/271 reads (34%) | catalogued as COSV100548985; called by muse, mutect2, varscan2
- RHOT1 | c.1008C>T p.F336= | Silent (SNP) | VAF 25/158 reads (16%) | catalogued as COSV100447276; called by muse, mutect2, varscan2
- SCN3A | c.3315T>A p.I1105= | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as COSV99327075; called by muse, mutect2, varscan2
- SCN3B | c.204C>G p.G68= | Silent (SNP) | VAF 46/197 reads (23%) | catalogued as COSV100173727, COSV54798179; called by muse, mutect2, varscan2
- SENP7 | c.843C>T p.S281= | Silent (SNP) | VAF 21/156 reads (13%) | catalogued as COSV100053193; called by muse, mutect2, varscan2
- SHOX2 | c.672C>T p.N224= (on ENST00000441443 / NM_006884.3; = p.N248= on NM_003030.4) | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as rs778141323, COSV101273795; called by muse, mutect2, varscan2
- SIDT1 | c.2331G>A p.E777= | Silent (SNP) | VAF 55/370 reads (15%) | catalogued as rs767609858, COSV53509207; called by muse, mutect2, varscan2
- SLC2A13 | c.591G>A p.A197= | Silent (SNP) | VAF 44/283 reads (16%) | catalogued as rs779427681, COSV99786503; called by muse, mutect2, varscan2
- SLC30A1 | c.378C>G p.V126= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100879132; called by muse, mutect2, varscan2
- TAT | c.630T>C p.A210= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as COSV100587633; called by muse, mutect2
- TENM3 | c.624G>A p.L208= | Silent (SNP) | VAF 50/269 reads (19%) | catalogued as COSV101305123; called by muse, mutect2, varscan2
- TTN | c.55539C>G p.S18513= (on ENST00000591111; = p.S11089= on NM_003319.4) | Silent (SNP) | VAF 58/380 reads (15%) | catalogued as rs371432689; called by mutect2, varscan2
- TTN | c.23349C>T p.V7783= (on ENST00000591111; = p.V6856= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100613700; called by muse, mutect2, varscan2
- ZEB1 | c.1101A>C p.S367= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100314428, COSV58038675; called by muse, mutect2, varscan2
- AGAP7P | n.1351G>A | RNA (SNP) | VAF 35/227 reads (15%) | catalogued as rs1554941301; called by muse, mutect2, varscan2
- ARSB | c.1213+23264G>T | Intron (SNP) | VAF 46/205 reads (22%) | catalogued as COSV99364790; called by muse, mutect2, varscan2
- STX2 | c.*69T>C | 3'UTR (SNP) | VAF 18/103 reads (17%) | catalogued as COSV99892873; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2940G>A | Intron (SNP) | VAF 35/203 reads (17%) | catalogued as COSV100314287; called by muse, mutect2, varscan2
- TTN | c.10360+1192A>G | Intron (SNP) | VAF 81/423 reads (19%) | catalogued as COSV100613701; called by muse, mutect2, varscan2
- XIST | n.9628C>G | RNA (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
